Somatic mutation profile of tumor specimen TCGA-D5-5541-01A (aliquot TCGA-D5-5541-01A-01D-1650-10) from TCGA case TCGA-D5-5541, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 63.3 years (23,109 days).
Specimen TCGA-D5-5541-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39e8f62b-bc62-4d14-a54d-ccff96762bf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-5541-10A (Blood Derived Normal), aliquot TCGA-D5-5541-10A-02D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/738d6df4-0374-47b0-a167-d0ba788cd4ba

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 40, Silent 16, Nonsense Mutation 8, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4474del p.A1492Pfs*15 | Frame Shift Del (DEL) | VAF 74/128 reads (58%) | catalogued as rs1131691144, COSV57338810, COSV57372621; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CNGA3 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893613, CM980376, COSV55622680; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 37/50 reads (74%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM2 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs769082387, COSV55864232; called by muse, varscan2
- AL121899.2 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs760403495, COSV67350431; called by muse, mutect2, varscan2
- APLNR | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373170562, COSV57241687; called by muse, mutect2, varscan2
- APOB | c.2064C>G p.I688M | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs774188993, COSV99267195; called by muse, mutect2, varscan2
- ARHGEF1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV100529150; called by muse, mutect2
- ARID1A | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 55/130 reads (42%) | catalogued as COSV100252204; called by muse, mutect2, varscan2
- BRICD5 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs374423982; called by muse, mutect2, varscan2
- CDC42EP3 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1206032439, COSV54874653; called by muse, mutect2, varscan2
- CDYL2 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV73653925; called by muse, mutect2, varscan2
- CLEC16A | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201076792, COSV55491109; called by muse, mutect2, varscan2
- CPED1 | c.2778dup p.H927Tfs*4 | Frame Shift Ins (INS) | VAF 52/198 reads (26%) | catalogued as rs777945397; called by mutect2, varscan2
- CPS1 | c.3322G>T p.A1108S | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as COSV51808589, COSV51820353; called by muse, mutect2, varscan2
- CSMD2 | c.4493T>A p.F1498Y | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53946447; called by muse, mutect2, varscan2
- DOK5 | c.899C>A p.P300Q | Missense Mutation (SNP) | VAF 269/346 reads (78%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52819240, COSV52820421, COSV52823946; called by muse, mutect2, varscan2
- DOK6 | c.923G>A p.S308N | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV66935783; called by muse, mutect2, varscan2
- E2F7 | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV59742499; called by muse, mutect2, varscan2
- ERLEC1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99483175; called by muse, mutect2
- FERMT1 | c.152A>C p.N51T | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV54096274; called by muse, mutect2, varscan2
- H1-7 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV58602829; called by muse, mutect2, varscan2
- HEMK1 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV99231718, COSV99231878; called by muse, varscan2
- HLA-E | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV64927794; called by muse, mutect2, varscan2
- HPS1 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs1243685743, COSV57269696; called by muse, mutect2, varscan2
- IL11 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.057); catalogued as rs1212524304, COSV52773515; called by muse, mutect2, varscan2
- KHDRBS3 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as COSV63414711; called by muse, mutect2
- KIT | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs755508624, COSV55396430; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KRT6A | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 164/433 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs745737972, COSV58106951; called by muse, mutect2, varscan2
- LACTB | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 96/321 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV56055651, COSV56056734; called by muse, mutect2, varscan2
- LARP1 | c.2995T>G p.Y999D (on ENST00000518297 / NM_033551.3; = p.Y922D on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60430216; called by muse, mutect2, varscan2
- LCMT1 | c.290T>A p.L97H | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66726615; called by muse, mutect2, varscan2
- MAGI2 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 312/540 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374007527; called by muse, mutect2, varscan2
- MUC5B | c.12676G>A p.G4226S | Missense Mutation (SNP) | VAF 97/393 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs551298472, COSV71591689; called by muse, mutect2, varscan2
- NCOA1 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV56050762; called by muse, mutect2
- NCOA2 | c.3766C>T p.Q1256* | Nonsense Mutation (SNP) | VAF 43/265 reads (16%) | catalogued as COSV51221919; called by muse, mutect2, varscan2
- NDST1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs754297456, COSV55790684; called by muse, mutect2, varscan2
- PLEKHG4B | c.1315C>T p.R439* (on ENST00000283426; = p.R795* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as rs747027011, COSV52052714; called by muse, mutect2
- POLR3GL | c.559_561del p.E187del | In Frame Del (DEL) | VAF 38/96 reads (40%) | catalogued as rs781986338; called by pindel, varscan2
- POU4F2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs747030570, COSV55582913; called by muse, mutect2, varscan2
- PRR14 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99788591; called by muse, mutect2
- PRR5L | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.112); catalogued as COSV61122948; called by muse, mutect2, varscan2
- SAP130 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs147076612; called by muse, mutect2, varscan2
- SNX20 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | catalogued as rs199531677, COSV100319303; called by muse, varscan2
- SYNE1 | c.23185A>T p.T7729S (on ENST00000367255 / NM_182961.4; = p.T7658S on NM_033071.3) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99574719; called by muse, mutect2, varscan2
- TGFBR1 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 147/417 reads (35%) | catalogued as rs200595614, COSV66625422; called by muse, mutect2, varscan2
- TRPC4 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1287965364, COSV58993391; called by muse, mutect2
- TTN | c.55016C>T p.P18339L (on ENST00000591111; = p.P10915L on NM_003319.4) | Missense Mutation (SNP) | VAF 87/150 reads (58%) | PolyPhen probably damaging (0.999); catalogued as COSV60257061; called by muse, mutect2, varscan2
- UQCR10 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV57458906; called by muse, mutect2, varscan2
- ZSCAN31 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 82/176 reads (47%) | catalogued as rs753739881, COSV60180879; called by muse, mutect2, varscan2
- HCN2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.069); called by muse, varscan2
- ASPM | c.5964G>A p.K1988= | Silent (SNP) | VAF 140/396 reads (35%) | catalogued as COSV54135863; called by muse, mutect2, varscan2
- CHAT | c.1668C>T p.S556= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs55702495, COSV100339693, COSV60324581; ClinVar: uncertain significance; called by muse, mutect2
- DENND3 | c.3462C>T p.A1154= | Silent (SNP) | VAF 35/251 reads (14%) | catalogued as rs750244823, COSV99371477; called by muse, mutect2, varscan2
- E2F7 | c.1599G>T p.V533= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs994775417, COSV59742518; called by muse, mutect2, varscan2
- EGR2 | c.1179C>T p.T393= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs965148587, COSV54346174; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPD1 | c.649C>T p.L217= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV99993857; called by muse, mutect2
- KLHDC8B | c.681G>A p.L227= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs1307311843, COSV60412395; called by muse, mutect2, varscan2
- LRP5 | c.4095C>T p.S1365= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs199576767; ClinVar: likely benign; called by muse, mutect2, varscan2
- MITF | c.366C>T p.L122= (on ENST00000448226 / NM_006722.3; = p.L16= on NM_000248.4) | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as rs373819498, COSV58832280; called by muse, mutect2, varscan2
- MYBPC2 | c.1881C>T p.D627= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs1405863127, COSV63096061; called by muse, mutect2, varscan2
- MYCBPAP | c.936C>T p.D312= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs145596456; called by muse, mutect2, varscan2
- NCAM2 | c.489C>T p.F163= | Silent (SNP) | VAF 76/248 reads (31%) | catalogued as rs1478826270, COSV53065860; called by muse, mutect2, varscan2
- NCOA1 | c.2586T>C p.T862= | Silent (SNP) | VAF 55/165 reads (33%) | catalogued as rs772920550, COSV56050753; called by muse, mutect2
- OXER1 | c.975C>T p.S325= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs769126172, COSV54311865; called by muse, mutect2, varscan2
- UBE3B | c.3039C>T p.S1013= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs1210154943, COSV61074628; called by muse, mutect2, varscan2
- ZMYND8 | c.2037A>C p.A679= (on ENST00000311275 / NM_001363741.2; = p.A699= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 95/980 reads (10%) | catalogued as COSV53694183; called by muse, mutect2
